Somatic mutation profile of cancer-model specimen HCM-WCMC-0747-C50-85A (3D Organoid, passage 10; aliquot HCM-WCMC-0747-C50-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-WCMC-0747-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 43.2 years (15,793 days).
Specimen HCM-WCMC-0747-C50-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6df3f361-e160-4f90-9be1-622dd3624c7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0747-C50-10A (Blood Derived Normal), aliquot HCM-WCMC-0747-C50-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a5786ce-9d9a-4f1f-9e51-70db6a01de93

The open-access MAF lists 4,865 somatic variants for this specimen: 3,658 protein-altering or splice-affecting, 1,006 silent, 201 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,132, Silent 1,006, Nonsense Mutation 460, Intron 128, 3'UTR 27, Splice Site 25, Splice Region 23, 5'Flank 17, 3'Flank 12, Frame Shift Ins 11, RNA 10, 5'UTR 7.

Variants (750 of 4,865; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3661C>T p.R1221C | Missense Mutation (SNP) | VAF 163/346 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751215, CM030401; ClinVar: pathogenic; called by muse, varscan2
- ARG1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 181/386 reads (47%) | catalogued as rs104893940, CM920106; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASPM | c.9319C>T p.R3107* | Nonsense Mutation (SNP) | VAF 118/373 reads (32%) | catalogued as rs199422187, CM092387, COSV54123750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6AP1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 46/668 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs878853277, CM166855, COSV63895463; ClinVar: pathogenic; called by muse, mutect2
- BRIP1 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 52/248 reads (21%) | catalogued as rs747604569, CM159015, COSV104386529, COSV52003721; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1137G>A p.T379= | Splice Region (SNP) | VAF 113/114 reads (99%) | catalogued as rs587783050, CS060517, COSV55733400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.4294C>T p.R1432* | Nonsense Mutation (SNP) | VAF 149/332 reads (45%) | catalogued as rs587779585, CM013250, COSV58591606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 96/230 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by muse, mutect2, varscan2
- DYNC2LI1 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 113/266 reads (42%) | catalogued as rs745930390, CM157152, COSV53182974; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 143/329 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs797045041, COSV58292419; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 158/329 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1258412021, COSV54063404, COSV54077108; called by muse, mutect2, varscan2
- KCNQ5 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 119/346 reads (34%) | catalogued as rs1554201137, COSV59651569; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRBA | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 195/409 reads (48%) | catalogued as rs199469664, CM125689; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MERTK | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 165/337 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878853354, CM148731, COSV54927455; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 180/353 reads (51%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2, varscan2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 117/214 reads (55%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NDUFAF2 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 93/190 reads (49%) | catalogued as rs137852863, CM053986, COSV56942088; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 268/273 reads (98%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.3316C>T p.R1106* | Nonsense Mutation (SNP) | VAF 188/384 reads (49%) | catalogued as rs202033121, CM094636; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 176/361 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 212/428 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 117/253 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PRPS1 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 274/569 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs1556300610, CM1412532, COSV104423748; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAG2 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 206/485 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1564997563, BM1516989; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SATB2 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 180/361 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.602); catalogued as rs1064795530, COSV53477421; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4934G>A p.R1645Q (on ENST00000303395 / NM_001202435.3; = p.R1634Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/350 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121917976, CM072001, CM1511233, COSV57662283; ClinVar: pathogenic; called by muse, varscan2
- SDHB | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 131/280 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs587782604, CM056696, CM086923, COSV64965048; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.4975C>T p.R1659* | Nonsense Mutation (SNP) | VAF 93/334 reads (28%) | catalogued as rs1394141324, CM085728, COSV100935534; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 133/283 reads (47%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TF | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 116/252 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); catalogued as rs121918680, CM024626, COSV53917909; ClinVar: pathogenic; called by muse, varscan2
- THRA | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 93/259 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866927537, COSV52841127; called by muse, mutect2, varscan2
- TMEM126A | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 183/383 reads (48%) | catalogued as rs121434508, CM092006, COSV58735100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 165/334 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs886039513, CM145649, COSV55497204; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 166/347 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV55285440; called by muse, mutect2, varscan2
- A3GALT2 | c.35G>T p.R12I | Missense Mutation (SNP) | VAF 140/322 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs1557808784; called by muse, mutect2, varscan2
- AAAS | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 164/361 reads (45%) | catalogued as rs751369041, CM065952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AADAC | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99233421; called by muse, mutect2, varscan2
- ABCA3 | c.1554C>A p.Y518* | Nonsense Mutation (SNP) | VAF 222/456 reads (49%) | catalogued as COSV57052448; called by muse, mutect2, varscan2
- ABCB6 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 167/341 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as rs147046586; called by muse, mutect2, varscan2
- ABCC8 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 134/341 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.96); catalogued as CM073980, CM133209; called by muse, mutect2, varscan2
- ABCE1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 107/257 reads (42%) | catalogued as COSV56846807; called by muse, mutect2, varscan2
- ABCG2 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 134/285 reads (47%) | catalogued as rs201034377, COSV52948355; called by muse, mutect2, varscan2
- ABHD12B | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 128/283 reads (45%) | catalogued as rs909563542; called by muse, mutect2, varscan2
- ABHD16B | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 194/380 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53863610; called by muse, mutect2, varscan2
- ABLIM1 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 144/410 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1457319900; called by muse, mutect2, varscan2
- AC008397.2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 125/348 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs201157838; called by muse, mutect2, varscan2
- AC099489.1 | c.4237G>A p.A1413T | Missense Mutation (SNP) | VAF 116/229 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs777140143; called by muse, mutect2, varscan2
- AC231657.3 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 132/268 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs782678518; called by muse, mutect2, varscan2
- ACADM | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769906625, COSV63720304; called by muse, mutect2, varscan2
- ACBD4 | c.659G>A p.R220H (on ENST00000376955 / NM_001378111.1; = p.P223= on NM_024722.4) | Missense Mutation (SNP) | VAF 205/386 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs557303418; called by muse, mutect2, varscan2
- ACE | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 215/445 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52013980; called by muse, mutect2
- ACOT9 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 185/379 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs774135140, COSV60539215; called by muse, mutect2, varscan2
- ACRBP | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 229/485 reads (47%) | catalogued as COSV57523840, COSV57524678; called by muse, mutect2, varscan2
- ACSM2B | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 150/335 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576087006, COSV100313142; called by muse, mutect2, varscan2
- ACSS1 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 166/385 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs752186614; called by muse, mutect2, varscan2
- ACTN2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 161/512 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV104426763, COSV63978633; called by muse, mutect2, varscan2
- ACTN2 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 172/541 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1270659015; called by muse, mutect2, varscan2
- ACTN3 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 144/342 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232811519, COSV72207678; called by muse, mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTR1A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 206/377 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV64024400; called by muse, mutect2, varscan2
- ACTR5 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 112/257 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs768469393; called by muse, mutect2, varscan2
- ACVR1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 122/299 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55116621; called by muse, mutect2, varscan2
- ADAL | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1344077571; called by muse, mutect2, varscan2
- ADAM15 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 233/686 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as rs754878868, COSV99665288; called by muse, mutect2, varscan2
- ADAM18 | c.1068T>G p.I356M | Missense Mutation (SNP) | VAF 127/296 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs201596679; called by muse, mutect2, varscan2
- ADAM29 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 130/337 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537404539, COSV63660881; called by muse, mutect2, varscan2
- ADAMTS12 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 197/424 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as rs146144250; called by muse, mutect2, varscan2
- ADAMTS18 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 134/134 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs775057284, COSV51408503; called by muse, mutect2, varscan2
- ADAMTS20 | c.2335C>A p.L779I | Missense Mutation (SNP) | VAF 104/225 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV101166252; called by muse, mutect2, varscan2
- ADCK1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 185/413 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs748957337, COSV99452248; called by muse, mutect2, varscan2
- ADCY10 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 187/633 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs895969024; called by muse, mutect2, varscan2
- ADCY7 | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 86/94 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170474430; called by muse, mutect2, varscan2
- ADD3 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 220/224 reads (98%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs767558945, COSV53321083; called by muse, mutect2, varscan2
- ADGRB3 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 142/323 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs779693752; called by muse, mutect2, varscan2
- ADGRF1 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV64800624; called by muse, mutect2, varscan2
- ADGRF5 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 161/333 reads (48%) | catalogued as COSV51937265; called by muse, mutect2, varscan2
- ADGRG4 | c.5974C>A p.L1992I | Missense Mutation (SNP) | VAF 293/610 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV54950689; called by muse, mutect2, varscan2
- ADGRG7 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 186/422 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751437270, COSV56301212, COSV99840688; called by muse, mutect2, varscan2
- ADGRL2 | c.2518G>T p.D840Y (on ENST00000370717 / NM_001366005.1; = p.D827Y on NM_012302.4) | Missense Mutation (SNP) | VAF 98/213 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1189334334, COSV54677538; called by muse, mutect2, varscan2
- ADGRL4 | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 112/220 reads (51%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs547554975, COSV66064053; called by muse, mutect2, varscan2
- ADGRV1 | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 191/392 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs755180090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.7771G>A p.E2591K | Missense Mutation (SNP) | VAF 162/322 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs757315634, COSV67978987; called by muse, mutect2, varscan2
- ADGRV1 | c.9481C>A p.P3161T | Missense Mutation (SNP) | VAF 127/293 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67991519; called by muse, mutect2, varscan2
- ADGRV1 | c.12425G>A p.R4142Q | Missense Mutation (SNP) | VAF 114/270 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1047782967, COSV67982871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADH6 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52955267; called by muse, mutect2, varscan2
- ADNP2 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 143/305 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs377757808; called by muse, mutect2, varscan2
- ADRA1D | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 278/565 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs1405319810; called by muse, mutect2, varscan2
- ADRB2 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 235/491 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60005280; called by muse, mutect2, varscan2
- ADTRP | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 192/413 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1443265858; called by muse, mutect2, varscan2
- AFF2 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 249/478 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60664320; called by mutect2, varscan2
- AGAP2 | c.2189G>A p.R730Q (on ENST00000547588 / NM_001122772.2; = p.R394Q on NM_014770.4) | Missense Mutation (SNP) | VAF 181/361 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs867161743, COSV57731334; called by muse, mutect2, varscan2
- AGBL2 | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 68/331 reads (21%) | catalogued as rs370788989; called by muse, mutect2, varscan2
- AGBL5 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 173/357 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100549432; called by muse, mutect2, varscan2
- AGL | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 96/318 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs947012690, COSV54051702; called by muse, mutect2, varscan2
- AGL | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 170/361 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as rs776599112, CM140956, COSV54048187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGMAT | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 128/266 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs768542408, COSV65435781; called by muse, mutect2
- AGMO | c.1008G>T p.K336N | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs752295082, COSV61118872; called by muse, mutect2, varscan2
- AGMO | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs1273447604, COSV61105744; called by muse, mutect2, varscan2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 238/239 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AGPS | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 151/300 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51560637, COSV51563645; called by muse, mutect2, varscan2
- AGPS | c.1350T>G p.F450L | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1337672529; called by muse, mutect2, varscan2
- AHNAK | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 221/449 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs745885352, COSV99947730; called by muse, mutect2, varscan2
- AKAP6 | c.6203C>T p.S2068L | Missense Mutation (SNP) | VAF 198/415 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772533351, COSV55205772; called by muse, mutect2, varscan2
- AKR7L | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs186763608; called by muse, mutect2, varscan2
- AL035461.3 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 151/281 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.515); catalogued as rs778702816; called by muse, mutect2, varscan2
- ALDH1B1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 216/456 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs770780314, COSV66620189; called by muse, varscan2
- ALG14 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 104/335 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs767402341, COSV64635180; called by muse, mutect2, varscan2
- ALMS1 | c.11161C>A p.L3721M | Missense Mutation (SNP) | VAF 136/290 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs267599449, COSV52502459; called by muse, varscan2
- ALPK2 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 136/284 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs766605419, COSV64491438; called by muse, mutect2, varscan2
- AMDHD1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 129/288 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201031842; called by muse, mutect2, varscan2
- AMER1 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 272/578 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs200339567; called by muse, varscan2
- AMFR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV51920352; called by muse, mutect2, varscan2
- AMMECR1L | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 135/317 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV55760188, COSV99761263; called by muse, mutect2, varscan2
- AMN1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 149/293 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as rs765159439, COSV55670682; called by muse, mutect2, varscan2
- ANGPT2 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100290422; called by muse, mutect2, varscan2
- ANGPTL7 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 162/327 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.068); catalogued as COSV63872036; called by mutect2, varscan2
- ANK1 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 209/405 reads (52%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.484); catalogued as rs767117624; called by muse, mutect2, varscan2
- ANKAR | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55617775; called by muse, mutect2, varscan2
- ANKFN1 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59450715; called by muse, mutect2, varscan2
- ANKK1 | c.724A>G p.M242V | Missense Mutation (SNP) | VAF 153/313 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1250130741; called by muse, mutect2, varscan2
- ANKRD20A1 | c.2980C>T p.L994F | Missense Mutation (SNP) | VAF 57/229 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1159652604; called by muse, mutect2, varscan2
- ANKRD26 | c.3058C>T p.R1020C | Missense Mutation (SNP) | VAF 169/360 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as rs761804757; called by muse, mutect2, varscan2
- ANKRD36 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.846); catalogued as rs946488323, COSV70736234; called by muse, mutect2, varscan2
- ANKRD36C | c.4764dup p.Q1589Tfs*11 | Frame Shift Ins (INS) | VAF 164/370 reads (44%) | catalogued as rs200875477; called by mutect2, varscan2
- ANKRD62 | c.608T>G p.F203C | Missense Mutation (SNP) | VAF 97/173 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.369); catalogued as COSV58409849; called by muse, mutect2, varscan2
- ANO8 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 209/426 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV50174155; called by muse, mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 256/478 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2, varscan2
- ANXA13 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as rs201212750, COSV51623085, COSV51626415; called by muse, mutect2, varscan2
- ANXA5 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 145/299 reads (48%) | catalogued as rs373965710; called by muse, mutect2, varscan2
- AOC2 | c.2118C>A p.F706L (on ENST00000253799 / NM_009590.4; = p.F679L on NM_001158.5) | Missense Mutation (SNP) | VAF 219/461 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs772005140, COSV53824129, COSV53826096; called by muse, mutect2, varscan2
- AP002748.5 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 116/271 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs759253107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1AR | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 189/450 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs367798505; called by muse, mutect2, varscan2
- APBA1 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 150/306 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595980, COSV99597291; called by mutect2, varscan2
- APOB | c.1931C>A p.S644Y | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs147173587, COSV51922803, COSV51933707; called by muse, mutect2, varscan2
- APOB | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 170/370 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as rs763352655, COSV51945515; called by muse, mutect2, varscan2
- APOBEC3F | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 166/303 reads (55%) | catalogued as rs773563808, COSV100415089; called by muse, mutect2, varscan2
- APOD | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 164/326 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs150503831; called by muse, mutect2, varscan2
- APOL5 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 266/505 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs887484530; called by muse, mutect2, varscan2
- ARAP2 | c.4871G>A p.R1624Q | Missense Mutation (SNP) | VAF 216/467 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1249697981, COSV58292022; called by muse, mutect2, varscan2
- ARHGAP11A | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 142/320 reads (44%) | catalogued as rs1487117985, COSV64381180; called by muse, varscan2
- ARHGAP31 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 106/238 reads (45%) | catalogued as COSV99957258; called by muse, mutect2, varscan2
- ARHGAP31 | c.2861C>A p.S954Y | Missense Mutation (SNP) | VAF 203/411 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51791145; called by muse, mutect2, varscan2
- ARHGAP32 | c.3757G>A p.E1253K (on ENST00000310343 / NM_001378025.1; = p.E904K on NM_014715.4) | Missense Mutation (SNP) | VAF 104/298 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.174); catalogued as rs768865360, COSV59847417; called by muse, mutect2, varscan2
- ARHGAP32 | c.2401C>A p.Q801K (on ENST00000310343 / NM_001378025.1; = p.Q452K on NM_014715.4) | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104403948; called by muse, mutect2
- ARHGAP35 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV68336597; called by muse, mutect2
- ARHGDIB | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as rs774401441, COSV56763076; called by muse, mutect2, varscan2
- ARHGEF10 | c.2012A>G p.D671G (on ENST00000398564; = p.D646G on NM_014629.4) | Missense Mutation (SNP) | VAF 212/423 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446957268; called by muse, mutect2, varscan2
- ARHGEF17 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 262/515 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1226836790; called by muse, mutect2, varscan2
- ARHGEF2 | c.331C>T p.R111* (on ENST00000361247 / NM_001162383.2; = p.R84* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 129/405 reads (32%) | catalogued as rs761084518; called by muse, mutect2, varscan2
- ARHGEF25 | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 270/548 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99677913; called by muse, mutect2, varscan2
- ARHGEF3 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 187/411 reads (45%) | catalogued as COSV99575465; called by muse, mutect2, varscan2
- ARL14 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 203/406 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV57899577; called by muse, varscan2
- ARL14EPL | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 36/336 reads (11%) | catalogued as rs981988957, COSV59948454, COSV59948566; called by muse, mutect2, varscan2
- ARMC2 | c.1305G>T p.K435N | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV64552188; called by muse, mutect2
- ARMC2 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 143/283 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs377734728; called by muse, mutect2, varscan2
- ARMC9 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 134/294 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV63020947; called by muse, mutect2, varscan2
- ARNTL | c.907G>A p.E303K (on ENST00000403290 / NM_001297719.2; = p.E302K on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs773491224, COSV100724712, COSV62986216; called by muse, mutect2, varscan2
- ARPC1A | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 140/271 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1159010389, COSV99501160; called by muse, mutect2, varscan2
- ARRDC3 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 121/242 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779678796; called by muse, mutect2, varscan2
- ARSJ | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 183/411 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV59540627; called by muse, mutect2, varscan2
- ARSK | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 126/270 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.324); catalogued as COSV66170448; called by muse, mutect2, varscan2
- ASAH1 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745596489; called by muse, mutect2, varscan2
- ASAH1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 99/244 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); catalogued as COSV50501972, COSV50504395; called by muse, mutect2, varscan2
- ASAP1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 149/311 reads (48%) | catalogued as COSV100727209; called by muse, mutect2, varscan2
- ASB14 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 181/359 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs758842851, COSV55700742; called by muse, mutect2, varscan2
- ASB15 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 149/316 reads (47%) | catalogued as COSV99306792; called by muse, mutect2, varscan2
- ASH1L | c.4024C>T p.R1342* | Nonsense Mutation (SNP) | VAF 148/395 reads (37%) | catalogued as COSV64213851; called by muse, mutect2, varscan2
- ASNS | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 139/258 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV51552598; called by muse, mutect2, varscan2
- ASPA | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99279217; called by muse, mutect2, varscan2
- ASPM | c.10269G>T p.K3423N | Missense Mutation (SNP) | VAF 81/311 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV104399271; called by mutect2, varscan2
- ASTN2 | c.2183C>T p.S728L (on ENST00000313400 / NM_001365069.1; = p.S677L on NM_014010.5) | Missense Mutation (SNP) | VAF 158/308 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144736118; called by muse, mutect2, varscan2
- ASXL1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 155/333 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60102435; called by muse, mutect2, varscan2
- ASXL2 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 108/272 reads (40%) | catalogued as COSV55456602; called by muse, mutect2, varscan2
- ASXL2 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 64/182 reads (35%) | catalogued as COSV55454380; called by muse, mutect2, varscan2
- ASXL3 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 164/369 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV99323704; called by muse, mutect2, varscan2
- ATAD2 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 138/305 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV99783984; called by muse, mutect2, varscan2
- ATE1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 156/333 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs773450449, COSV56435136; called by muse, mutect2, varscan2
- ATF2 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 180/389 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs147478928; called by muse, mutect2, varscan2
- ATF7IP | c.3292C>T p.R1098* | Nonsense Mutation (SNP) | VAF 97/217 reads (45%) | catalogued as rs770191292, COSV53770969; called by muse, mutect2, varscan2
- ATG12 | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 161/299 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.721); catalogued as rs561465491; called by muse, mutect2, varscan2
- ATG14 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 140/297 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs554503349, COSV55955889; called by muse, mutect2, varscan2
- ATG2B | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 95/234 reads (41%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.963); catalogued as rs772425977, COSV55890367; called by muse, mutect2, varscan2
- ATP10A | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 152/335 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63518880; called by muse, mutect2, varscan2
- ATP1A2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 180/766 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs748881406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A2 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 179/386 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs757914881, CM113597; called by muse, mutect2, varscan2
- ATP5PB | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 169/390 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751833359, COSV52384704; called by muse, mutect2, varscan2
- ATP6AP2 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 111/258 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV101011496, COSV65797177; called by muse, mutect2, varscan2
- ATP6V0A4 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 147/293 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147512254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V1G3 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 76/281 reads (27%) | catalogued as rs776856347, COSV55278194, COSV99811103; called by muse, mutect2, varscan2
- ATP8A1 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 114/234 reads (49%) | catalogued as rs755553887, COSV100046625; called by muse, mutect2, varscan2
- ATP8B1 | c.3041G>A p.R1014Q | Missense Mutation (SNP) | VAF 139/299 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.211); catalogued as rs756828618; called by muse, mutect2, varscan2
- ATP8B2 | c.3133G>A p.D1045N (on ENST00000672630; = p.D1012N on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/486 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs775307615; called by muse, varscan2
- ATP8B4 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 63/160 reads (39%) | catalogued as rs940798819, COSV52710402; called by muse, mutect2, varscan2
- ATP8B4 | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 130/278 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV52726883; called by mutect2, varscan2
- ATR | c.4507C>T p.R1503* | Nonsense Mutation (SNP) | VAF 116/230 reads (50%) | catalogued as rs754602382, COSV63387617; called by muse, mutect2, varscan2
- ATR | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV63384749; called by muse, varscan2
- ATRX | c.5386G>T p.D1796Y | Missense Mutation (SNP) | VAF 180/413 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970229; called by muse, varscan2
- ATXN2 | c.3632C>T p.T1211M (on ENST00000550104; = p.T1051M on NM_002973.4) | Missense Mutation (SNP) | VAF 202/443 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1198968756, COSV57981626; called by muse, mutect2, varscan2
- B2M | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 200/419 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs986783978; called by muse, mutect2, varscan2
- B4GALNT2 | c.200G>T p.R67I | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs777942057; called by muse, mutect2, varscan2
- BACH1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 129/295 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750785692, COSV54518596; called by muse, mutect2, varscan2
- BARD1 | c.2221G>T p.D741Y | Missense Mutation (SNP) | VAF 215/424 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs587780029, COSV53616112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1A | c.4508C>T p.S1503L | Missense Mutation (SNP) | VAF 140/284 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1389574742, COSV62409622; called by muse, mutect2, varscan2
- BAZ2B | c.6416T>G p.F2139C | Missense Mutation (SNP) | VAF 153/325 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58603397; called by muse, mutect2, varscan2
- BCAS3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 127/270 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs773183785, COSV101175451; called by muse, mutect2, varscan2
- BCAS3 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 107/266 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as rs140207277, COSV66775048; called by muse, mutect2, varscan2
- BCCIP | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 171/387 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751497919, COSV104372773; called by muse, mutect2, varscan2
- BCL7C | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 137/308 reads (44%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1319181407; called by muse, mutect2, varscan2
- BCO2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 193/422 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs200317622, COSV63065053; called by muse, mutect2, varscan2
- BDP1 | c.5479C>T p.R1827C | Missense Mutation (SNP) | VAF 275/578 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1441660115, COSV62430653; called by muse, mutect2, varscan2
- BEND2 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 194/423 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as rs1366859789; called by muse, mutect2, varscan2
- BEND3 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 179/383 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.887); catalogued as rs1167437884, COSV64681720; called by muse, mutect2, varscan2
- BEND4 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 161/326 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV72468902; called by muse, mutect2, varscan2
- BEX1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 288/583 reads (49%) | catalogued as COSV101022493; called by muse, varscan2
- BEX1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 298/620 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as COSV65579974; called by muse, varscan2
- BICC1 | c.2795-1G>T p.X932_splice | Splice Site (SNP) | VAF 81/175 reads (46%) | catalogued as rs773328701; called by muse, mutect2, varscan2
- BIRC6 | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 52/522 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772811050, COSV101427959; called by muse, mutect2
- BIRC6 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 139/285 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196110; called by muse, mutect2, varscan2
- BLOC1S5 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 107/229 reads (47%) | catalogued as COSV55241687; called by muse, mutect2, varscan2
- BMI1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV64959350; called by muse, mutect2, varscan2
- BMP2 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 179/385 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV66578028; called by muse, mutect2, varscan2
- BMP7 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 208/407 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV67780098; called by muse, mutect2, varscan2
- BMPER | c.1793A>G p.Y598C | Missense Mutation (SNP) | VAF 145/324 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs1002066204; called by muse, mutect2, varscan2
- BMT2 | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 137/286 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV51778386; called by muse, mutect2, varscan2
- BNC2 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 229/483 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs756459154, COSV101033320, COSV66149708; called by muse, mutect2, varscan2
- BOD1L1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 159/356 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50015843, COSV99240474; called by muse, mutect2, varscan2
- BOP1 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 263/543 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs782184080; called by muse, mutect2
- BPI | c.593G>A p.R198Q (on ENST00000262865; = p.R194Q on NM_001725.3) | Missense Mutation (SNP) | VAF 128/274 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs749629986, COSV53404895, COSV53408318; called by muse, varscan2
- BRAF | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 165/328 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV56144127; called by muse, mutect2, varscan2
- BRCA2 | c.3775A>C p.S1259R | Missense Mutation (SNP) | VAF 95/194 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as rs587782071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCC3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV57462323; called by muse, varscan2
- BRD9 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 136/338 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); catalogued as rs754959562; called by muse, mutect2
- BRINP2 | c.2104C>A p.L702I | Missense Mutation (SNP) | VAF 163/486 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV64175866, COSV64180538; called by muse, varscan2
- BRPF1 | c.1983+7G>A | Splice Region (SNP) | VAF 143/290 reads (49%) | catalogued as rs751452778; called by muse, mutect2, varscan2
- BRWD3 | c.5237G>A p.R1746Q | Missense Mutation (SNP) | VAF 239/533 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.953); catalogued as rs918551619, COSV100956683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 105/242 reads (43%) | catalogued as COSV64748961, COSV64754484; called by muse, mutect2, varscan2
- BTBD7 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 222/453 reads (49%) | catalogued as rs1017916547, COSV100597990, COSV58285585; called by muse, mutect2, varscan2
- BTK | c.1645G>T p.D549Y | Missense Mutation (SNP) | VAF 140/318 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58123080; called by muse, mutect2, varscan2
- BTK | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 209/431 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100437735; called by muse, mutect2, varscan2
- BTN2A1 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 239/520 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs546770853, COSV57002135; called by muse, mutect2, varscan2
- BTN3A2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 142/255 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs774256825, COSV62686837; called by muse, mutect2, varscan2
- BTNL3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 219/458 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs778473610, COSV61564442; called by muse, mutect2, varscan2
- BTNL9 | c.560G>T p.R187I | Missense Mutation (SNP) | VAF 218/470 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV59794831, COSV59795131; called by muse, mutect2, varscan2
- BZW1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 147/307 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV63349698; called by muse, mutect2, varscan2
- C14orf39 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 96/235 reads (41%) | catalogued as COSV100408121; called by muse, mutect2, varscan2
- C16orf89 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 184/384 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs1366296763, COSV60125129; called by muse, varscan2
- C17orf99 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 172/361 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs980212271; called by muse, varscan2
- C17orf99 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 218/458 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs948785372; called by muse, varscan2
- C1QL4 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 252/497 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs750966716, COSV57743425; called by muse, mutect2, varscan2
- C1QTNF12 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 204/416 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs369520877; called by muse, mutect2, varscan2
- C1QTNF3 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 222/484 reads (46%) | catalogued as rs754470860, COSV51467668; called by muse, mutect2, varscan2
- C1S | c.1932G>T p.K644N | Missense Mutation (SNP) | VAF 119/409 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1565625243, COSV61071065; called by muse, mutect2, varscan2
- C1orf87 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 230/416 reads (55%) | catalogued as rs147997086, COSV64596556; called by muse, mutect2
- C21orf91 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs201245548; called by muse, mutect2
- C22orf15 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 136/309 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.088); catalogued as rs1202464682; called by muse, mutect2, varscan2
- C2CD5 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 116/225 reads (52%) | catalogued as COSV61723130, COSV61724471; called by muse, mutect2, varscan2
- C2CD5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 198/388 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61722731; called by muse, mutect2, varscan2
- C2orf16 | c.3887G>A p.R1296Q | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs755976275, COSV62675099; called by muse, mutect2, varscan2
- C2orf42 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 108/212 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs1206663492; called by muse, mutect2, varscan2
- C2orf78 | c.1824G>T p.K608N | Missense Mutation (SNP) | VAF 158/388 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV68519412; called by muse, mutect2, varscan2
- C3 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 194/424 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs149395057; called by muse, varscan2
- C7 | c.1710C>A p.F570L | Missense Mutation (SNP) | VAF 112/268 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV100496155; called by muse, mutect2, varscan2
- C7orf31 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 126/272 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs531648664, COSV52216035; called by muse, mutect2, varscan2
- CAB39L | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 125/263 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs780505672, COSV61713671; called by muse, mutect2, varscan2
- CACNA1F | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 25/604 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.059); catalogued as rs782709793, COSV104403435; called by muse, mutect2
- CACNB2 | c.1075G>A p.E359K (on ENST00000324631 / NM_201596.3; = p.E304K on NM_000724.4) | Missense Mutation (SNP) | VAF 140/276 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV56633541; called by muse, mutect2, varscan2
- CACNB4 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 200/370 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs767538753, COSV52399686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG6 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV53165592; called by muse, mutect2, varscan2
- CADM4 | c.1158C>A p.F386L | Missense Mutation (SNP) | VAF 126/283 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs1339804405, COSV55929254; called by muse, mutect2, varscan2
- CALR3 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 148/329 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs550089146, COSV54168698; called by muse, mutect2, varscan2
- CAMSAP2 | c.3964C>T p.R1322C (on ENST00000236925 / NM_001297707.2; = p.R1311C on NM_203459.3) | Missense Mutation (SNP) | VAF 143/492 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs140682641; called by muse, mutect2, varscan2
- CAPN2 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 150/453 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1010016325, COSV54337515; called by muse, mutect2, varscan2
- CAPN5 | c.1297G>A p.E433K (on ENST00000456580; = p.E393K on NM_004055.5) | Missense Mutation (SNP) | VAF 161/283 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs369845664; called by muse, mutect2, varscan2
- CAPN6 | c.872G>A p.W291* | Nonsense Mutation (SNP) | VAF 127/331 reads (38%) | catalogued as COSV60694892; called by muse, mutect2, varscan2
- CAPN9 | c.809G>T p.R270I | Missense Mutation (SNP) | VAF 160/469 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV55232544; called by muse, mutect2, varscan2
- CASK | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 136/299 reads (45%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs868537608, COSV59374892; called by muse, mutect2, varscan2
- CASP1 | c.718C>T p.R240W (on ENST00000436863 / NM_033292.4; = p.R219W on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 208/433 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1407049827; called by muse, mutect2, varscan2
- CASP8 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51846504, COSV99965286, COSV99965729; called by muse, mutect2, varscan2
- CATSPERG | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 160/304 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1238559379, COSV53046637; called by muse, mutect2, varscan2
- CATSPERG | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 190/399 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs1183951583; called by muse, mutect2, varscan2
- CAVIN1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 41/626 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs201945184; called by muse, mutect2
- CBWD2 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 154/316 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52073508; called by mutect2, varscan2
- CBX3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 69/426 reads (16%) | catalogued as COSV61761318; called by muse, mutect2, varscan2
- CCAR1 | c.3289T>G p.L1097V | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.987); catalogued as rs1040189895, COSV99771223; called by muse, mutect2, varscan2
- CCDC141 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs959221473, COSV69457431; called by muse, mutect2, varscan2
- CCDC141 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 159/372 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV69457684; called by muse, mutect2, varscan2
- CCDC149 | c.1130C>T p.S377L (on ENST00000635206 / NM_001330643.2; = p.S366L on NM_173463.5) | Missense Mutation (SNP) | VAF 172/364 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as rs373188183; called by muse, varscan2
- CCDC168 | c.19385G>T p.R6462I | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59419015; called by muse, mutect2
- CCDC168 | c.19118C>T p.A6373V | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.708); catalogued as COSV59424591; called by muse, mutect2
- CCDC168 | c.16274G>T p.R5425I | Missense Mutation (SNP) | VAF 211/461 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV104400445; called by muse, mutect2, varscan2
- CCDC174 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 109/203 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs201187132; called by muse, varscan2
- CCDC185 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 224/729 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs1359680074, COSV64820536; called by muse, mutect2, varscan2
- CCDC42 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 78/258 reads (30%) | catalogued as COSV53449838; called by muse, varscan2
- CCDC42 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs536001412, COSV53448635; called by muse, varscan2
- CCDC57 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 174/506 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs368209009; called by muse, varscan2
- CCDC6 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 123/247 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.338); catalogued as COSV54055823; called by muse, mutect2, varscan2
- CCDC73 | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 91/221 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs376825549; called by muse, mutect2, varscan2
- CCDC88C | c.4703C>T p.S1568L | Missense Mutation (SNP) | VAF 135/296 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as rs752668368, COSV57796258; called by muse, mutect2, varscan2
- CCKBR | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 242/546 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs773790618, COSV58106563; called by muse, mutect2, varscan2
- CCN2 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 190/413 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63466512; called by muse, mutect2, varscan2
- CCNT1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 176/377 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as rs768066318, COSV99980731; called by muse, mutect2, varscan2
- CCPG1 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 182/384 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs753064740; called by muse, mutect2, varscan2
- CCSER1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 142/255 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs745548077, COSV100390706, COSV61437396; called by muse, mutect2, varscan2
- CCSER2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 162/338 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs200068948, COSV56512306; called by muse, mutect2, varscan2
- CCT8 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 119/406 reads (29%) | catalogued as COSV54506982; called by muse, mutect2, varscan2
- CD101 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 220/469 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200228819; called by muse, mutect2, varscan2
- CD22 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 136/303 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as rs575288611, COSV99323215; called by muse, mutect2, varscan2
- CD2AP | c.1109-1G>T p.X370_splice | Splice Site (SNP) | VAF 76/152 reads (50%) | catalogued as rs966480634; called by mutect2, varscan2
- CD69 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as rs142870511; called by muse, mutect2, varscan2
- CDC26 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 113/235 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs764264213, COSV65252464, COSV65252631; called by muse, mutect2, varscan2
- CDC40 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 167/317 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1244226490, COSV57008311; called by muse, mutect2, varscan2
- CDC73 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 97/463 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072926, COSV66465222; called by muse, mutect2, varscan2
- CDH2 | c.745A>G p.N249D | Missense Mutation (SNP) | VAF 143/289 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.069); catalogued as COSV52297179; called by muse, mutect2, varscan2
- CDH23 | c.1450-1G>A p.X484_splice | Splice Site (SNP) | VAF 130/264 reads (49%) | catalogued as rs747981278; called by muse, mutect2, varscan2
- CDH5 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1342694698; called by muse, mutect2, varscan2
- CDK15 | c.443G>A p.R148Q (on ENST00000652192 / NM_001366386.2; = p.R97Q on NM_139158.2) | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370446004; called by muse, mutect2, varscan2
- CDK19 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 128/296 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.34); catalogued as rs953895657; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 174/341 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs141387242; called by muse, mutect2, varscan2
- CDK7 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 141/326 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56511769, COSV56515140; called by muse, mutect2, varscan2
- CDKL5 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 204/381 reads (54%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV66110977; called by muse, mutect2, varscan2
- CDNF | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 110/229 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV101012390; called by muse, mutect2, varscan2
- CDYL | c.748G>A p.E250K (on ENST00000328908 / NM_001368125.1; = p.E196K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/375 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs372980060, COSV59360015; called by muse, mutect2, varscan2
- CEACAM18 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 172/334 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV101140335; called by muse, varscan2
- CEL | c.642C>A p.F214L (on ENST00000673714; = p.F211L on NM_001807.6) | Missense Mutation (SNP) | VAF 154/363 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV60827156; called by muse, mutect2, varscan2
- CELSR2 | c.6107T>G p.F2036C | Missense Mutation (SNP) | VAF 88/307 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV99604605; called by muse, mutect2, varscan2
- CEMIP | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 158/318 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as rs756288191, COSV54993786; called by muse, mutect2, varscan2
- CENPE | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs866905901, COSV54378711; called by muse, mutect2, varscan2
- CENPF | c.5911T>C p.S1971P | Missense Mutation (SNP) | VAF 144/489 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV65274736; called by muse, mutect2, varscan2
- CEP126 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 121/295 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432108672, COSV54822807; called by muse, mutect2, varscan2
- CEP162 | c.1920C>A p.F640L | Missense Mutation (SNP) | VAF 148/295 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.12); catalogued as COSV100003406; called by muse, mutect2, varscan2
- CEP290 | c.6634G>T p.E2212* | Nonsense Mutation (SNP) | VAF 87/209 reads (42%) | catalogued as COSV58350782; called by muse, mutect2, varscan2
- CEP290 | c.3037G>T p.E1013* | Nonsense Mutation (SNP) | VAF 92/223 reads (41%) | catalogued as CM072942, COSV58350039; called by mutect2, varscan2
- CEP41 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 209/390 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1210916591; called by muse, mutect2, varscan2
- CERS3 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 113/249 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52565563; called by muse, mutect2, varscan2
- CERS4 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 140/380 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1407588961; called by muse, mutect2, varscan2
- CERT1 | c.1921C>T p.R641* (on ENST00000405807 / NM_001130105.1; = p.R513* on NM_005713.3) | Nonsense Mutation (SNP) | VAF 164/347 reads (47%) | catalogued as COSV54656028, COSV54662581; called by muse, mutect2, varscan2
- CES3 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 206/208 reads (99%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs376329904, COSV57593280; called by muse, mutect2, varscan2
- CETN2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 144/314 reads (46%) | catalogued as COSV100938618; called by muse, mutect2, varscan2
- CFAP45 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 195/580 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100928630; called by muse, mutect2, varscan2
- CFAP57 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 190/381 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749165112; called by muse, mutect2, varscan2
- CFAP91 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 184/372 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142545565; called by muse, mutect2, varscan2
- CFHR1 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 142/277 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57626879; called by muse, mutect2, varscan2
- CGB7 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 147/647 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs1321110880; called by muse, mutect2, varscan2
- CGNL1 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 158/305 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs772369065; called by muse, mutect2, varscan2
- CHD2 | c.4711G>A p.D1571N | Missense Mutation (SNP) | VAF 120/252 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.2); catalogued as rs780123418; called by muse, mutect2, varscan2
- CHD8 | c.1444C>T p.R482* (on ENST00000646647 / NM_001170629.2; = p.R203* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 285/583 reads (49%) | catalogued as COSV67870230; called by muse, mutect2, varscan2
- CHI3L2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 220/486 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs138664314, COSV63873542; called by muse, mutect2, varscan2
- CHM | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 24/479 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1460971688, COSV63301266; called by muse, mutect2
- CHRM4 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 183/431 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as rs780553103, COSV100708753; called by muse, mutect2, varscan2
- CHRNA9 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 169/427 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs139982841, CM1414136; called by muse, mutect2
- CHST13 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 252/537 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs755426222; called by muse, varscan2
- CHST7 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 320/702 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV52099846; called by muse, mutect2, varscan2
- CIP2A | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767069025, COSV55418459; called by muse, mutect2, varscan2
- CISD3 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 245/519 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1353251564; called by muse, mutect2, varscan2
- CKAP2 | c.305C>A p.P102H (on ENST00000378037 / NM_001098525.2; = p.P101H on NM_018204.5) | Missense Mutation (SNP) | VAF 170/338 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51620833; called by muse, mutect2, varscan2
- CKM | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 170/396 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as rs200170574, COSV55532790; called by muse, mutect2, varscan2
- CLASP2 | c.3938C>A p.S1313Y (on ENST00000359576; = p.S1312Y on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/329 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV56281402; called by muse, mutect2, varscan2
- CLCA1 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 117/254 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs904199511; called by muse, mutect2, varscan2
- CLDN10 | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 119/283 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs770886300, COSV100176118; called by muse, mutect2, varscan2
- CLEC5A | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 117/241 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV69397018; called by muse, mutect2, varscan2
- CLIC6 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 140/475 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); catalogued as rs955086173; called by muse, mutect2, varscan2
- CLSTN1 | c.640G>A p.D214N (on ENST00000377298 / NM_001009566.3; = p.D204N on NM_014944.4) | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259052061, COSV100790585; called by muse, mutect2
- CMKLR1 | c.995C>A p.S332Y (on ENST00000312143 / NM_001142344.2; = p.S330Y on NM_004072.3) | Missense Mutation (SNP) | VAF 176/343 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56436276; called by muse, mutect2, varscan2
- CNKSR3 | c.1578G>T p.K526N | Missense Mutation (SNP) | VAF 181/373 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs1209760782; called by muse, mutect2, varscan2
- CNTLN | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 101/233 reads (43%) | catalogued as rs898138601, COSV52083406; called by muse, mutect2, varscan2
- CNTN6 | c.1550T>C p.I517T | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63171758; called by muse, mutect2
- CNTNAP5 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 143/309 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757108906, COSV70486167; called by muse, mutect2, varscan2
- COL11A1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 94/191 reads (49%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.905); catalogued as rs1341498364, COSV62186825; called by muse, mutect2, varscan2
- COL14A1 | c.3358C>T p.R1120* | Nonsense Mutation (SNP) | VAF 122/234 reads (52%) | catalogued as rs779378321, COSV52852069, COSV52861310; called by muse, mutect2, varscan2
- COL15A1 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 108/236 reads (46%) | catalogued as COSV100897626; called by mutect2, varscan2
- COL20A1 | c.2079C>A p.I693= | Splice Region (SNP) | VAF 210/399 reads (53%) | catalogued as COSV100491630; called by muse, mutect2, varscan2
- COL21A1 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770639332, COSV55161169, COSV55161225; called by muse, varscan2
- COL21A1 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 205/415 reads (49%) | catalogued as COSV55158041; called by muse, mutect2, varscan2
- COL24A1 | c.4835C>T p.S1612L | Missense Mutation (SNP) | VAF 176/418 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs773684520, COSV65314341; called by muse, mutect2, varscan2
- COL24A1 | c.3982C>A p.L1328I | Missense Mutation (SNP) | VAF 138/302 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV65304646, COSV65314258; called by muse, mutect2, varscan2
- COL4A2 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 38/735 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1302775228; called by muse, mutect2
- COL4A5 | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 127/243 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60356306; called by muse, mutect2, varscan2
- COL6A1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 203/437 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.393); catalogued as rs200389937; called by muse, mutect2, varscan2
- COL6A5 | c.2878G>T p.E960* | Nonsense Mutation (SNP) | VAF 148/348 reads (43%) | catalogued as COSV55216074; called by muse, mutect2, varscan2
- COL6A5 | c.7504G>A p.D2502N (on ENST00000312481; = p.D2498N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/328 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs752185068, COSV99593495; called by muse, mutect2, varscan2
- COL9A1 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 140/309 reads (45%) | catalogued as COSV57879746; called by muse, mutect2, varscan2
- COLGALT2 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 91/319 reads (29%) | catalogued as rs373361853, COSV62298805; called by muse, mutect2, varscan2
- COPB1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 148/328 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369909236; called by muse, varscan2
- COQ8A | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 261/826 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143816043; called by muse, mutect2, varscan2
- COQ8A | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 169/520 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs1558208533, COSV64656813; called by muse, mutect2, varscan2
- CP | c.1918G>T p.D640Y | Missense Mutation (SNP) | VAF 201/398 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CD067161, CP025132, COSV52832203; called by muse, mutect2, varscan2
- CPA1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 231/454 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148329227, COSV50575831; called by muse, mutect2, varscan2
- CPD | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 157/291 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs749464593, COSV99852783; called by muse, mutect2, varscan2
- CPN1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 101/215 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1365395803; called by muse, mutect2, varscan2
- CPVL | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); catalogued as rs1487305020; called by muse, mutect2, varscan2
- CRB2 | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 287/602 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs542637649; called by muse, mutect2, varscan2
- CRNN | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 164/593 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs184532873; called by muse, mutect2
- CROCC | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 125/560 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs751566850; called by muse, mutect2, varscan2
- CRYBG2 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 162/341 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1203773831, COSV57485573; called by muse, mutect2, varscan2
- CRYBG3 | c.3117G>T p.K1039N | Missense Mutation (SNP) | VAF 145/280 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs545501003; called by mutect2, varscan2
- CSF2RA | c.615C>A p.F205L | Missense Mutation (SNP) | VAF 201/434 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs750757416, COSV62626327; called by muse, mutect2, varscan2
- CSGALNACT1 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 128/289 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV59974939; called by muse, mutect2, varscan2
- CSMD1 | c.4317C>A p.F1439L (on ENST00000520002; = p.F1438L on NM_033225.6) | Missense Mutation (SNP) | VAF 129/308 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as COSV59298436; called by muse, mutect2, varscan2
- CSMD2 | c.8389C>T p.R2797W | Missense Mutation (SNP) | VAF 217/452 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); catalogued as rs746116665, COSV53890915; called by muse, mutect2, varscan2
- CSMD2 | c.4877C>T p.S1626L | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs1318907091, COSV53931302; called by muse, mutect2, varscan2
- CSMD3 | c.8542C>T p.R2848* (on ENST00000297405 / NM_001363185.1; = p.R2679* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 125/364 reads (34%) | catalogued as COSV52187779; called by muse, mutect2, varscan2
- CSMD3 | c.2032G>A p.D678N (on ENST00000297405 / NM_001363185.1; = p.D574N on NM_052900.3) | Missense Mutation (SNP) | VAF 148/368 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.418); catalogued as rs142207091, COSV99838134; called by muse, mutect2, varscan2
- CSNK1D | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 118/229 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs774858511, COSV53925579; called by muse, mutect2, varscan2
- CSNK2A1 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 144/312 reads (46%) | catalogued as COSV104372006; called by muse, mutect2, varscan2
- CTC1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 156/330 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs368398609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTDP1 | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 277/581 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777623040, COSV50001698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.2258C>A p.S753Y | Missense Mutation (SNP) | VAF 171/376 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58153166; called by muse, mutect2, varscan2
- CTNNB1 | c.472A>C p.K158Q | Missense Mutation (SNP) | VAF 133/311 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV100846499; called by muse, mutect2, varscan2
- CTNND1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 179/397 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1406000983, COSV62383129, COSV62384953; called by muse, mutect2, varscan2
- CTSC | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 220/439 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1324949386; called by muse, mutect2, varscan2
- CTSG | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 170/384 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.051); catalogued as rs759013839, COSV53534623; called by muse, mutect2, varscan2
- CTSH | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs1307842406; called by muse, mutect2, varscan2
- CUBN | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64701968; called by muse, mutect2, varscan2
- CUL2 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 131/270 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs749443608, COSV66078880; called by muse, mutect2, varscan2
- CWC22 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 192/354 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.921); catalogued as rs200967500; called by muse, mutect2, varscan2
- CXCR3 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 298/621 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65461879; called by muse, mutect2, varscan2
- CYB561D1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 248/500 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1234971236, COSV100149777; called by muse, mutect2, varscan2
- CYP17A1 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 221/443 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV64004932; called by muse, mutect2, varscan2
- CYP2A6 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 175/388 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs773401076; called by muse, mutect2, varscan2
- CYP2J2 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 100/208 reads (48%) | catalogued as rs899892667, COSV64605512; called by mutect2, varscan2
- CYP2U1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 298/565 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV60549626; called by muse, mutect2, varscan2
- CYP3A4 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60504759; called by muse, mutect2, varscan2
- CYP4X1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 173/404 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs749036731; called by muse, mutect2, varscan2
- CYP4X1 | c.1512G>T p.K504N | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV64150677; called by muse, mutect2, varscan2
- DAB2IP | c.493C>A p.L165I (on ENST00000408936; = p.L137I on NM_032552.3) | Missense Mutation (SNP) | VAF 163/351 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52256933; called by muse, mutect2, varscan2
- DACT1 | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 239/475 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60023876; called by muse, mutect2, varscan2
- DAO | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201583577; called by muse, mutect2, varscan2
- DAPK1 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 150/305 reads (49%) | catalogued as COSV100800726; called by muse, mutect2, varscan2
- DBF4B | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as rs774436262, COSV59258932, COSV59261867; called by muse, mutect2, varscan2
- DBH | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 210/456 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368994366; called by muse, mutect2, varscan2
- DCAF13 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 144/272 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1425272025, COSV52570614; called by muse, mutect2, varscan2
- DCAF17 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CD086166; called by mutect2, varscan2
- DCAF4L1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 15/349 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.238); catalogued as rs1405508476, COSV100295574; called by muse, mutect2
- DCAF6 | c.2242C>T p.R748W (on ENST00000312263 / NM_001349778.1; = p.R768W on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 173/608 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745724831; called by muse, mutect2, varscan2
- DCLK2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 164/343 reads (48%) | catalogued as COSV56200287; called by muse, mutect2, varscan2
- DCLRE1A | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 179/325 reads (55%) | catalogued as rs1212761218, COSV100800363; called by mutect2, varscan2
- DCT | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 39/371 reads (11%) | catalogued as rs200349922, COSV65467774; called by muse, mutect2, varscan2
- DCTN3 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as rs765619518; called by muse, mutect2, varscan2
- DDB1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs141900083; called by muse, mutect2, varscan2
- DDR2 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 151/525 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.74); catalogued as COSV63375079; called by muse, varscan2
- DDX10 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 91/214 reads (43%) | catalogued as COSV100489936; called by muse, mutect2, varscan2
- DDX17 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 213/444 reads (48%) | catalogued as COSV53247135, COSV53249825; called by muse, mutect2, varscan2
- DDX23 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 149/306 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV56397324; called by muse, varscan2
- DDX25 | c.1243C>A p.L415I | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as COSV54989917; called by muse, mutect2
- DDX53 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 263/548 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60070174; called by muse, mutect2, varscan2
- DEDD | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 173/584 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs754848698, COSV63502143; called by muse, mutect2, varscan2
- DENND2C | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 128/362 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs779519005, COSV67924337; called by muse, mutect2, varscan2
- DEPDC1B | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 96/193 reads (50%) | catalogued as rs575323127, COSV54009042; called by muse, mutect2, varscan2
- DEPDC1B | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 103/224 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs201451342, COSV54013086; called by muse, mutect2, varscan2
- DERA | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 27/406 reads (7%) | catalogued as rs1362794638, COSV101397517; called by muse, mutect2
- DERL2 | c.238C>A p.R80S | Missense Mutation (SNP) | VAF 116/270 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50148031; called by mutect2, varscan2
- DGKD | c.3301G>A p.E1101K (on ENST00000264057 / NM_152879.3; = p.E1057K on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/273 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as rs991285626; called by muse, mutect2, varscan2
- DHRS7C | c.449C>T p.A150V (on ENST00000330255 / NM_001220493.2; = p.A149V on NM_001105571.3) | Missense Mutation (SNP) | VAF 163/340 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs773513074; called by muse, mutect2, varscan2
- DHTKD1 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 158/570 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs371485560; called by muse, mutect2, varscan2
- DHX40 | c.1913G>T p.R638I | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99232976; called by muse, mutect2, varscan2
- DICER1 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as rs886037667, COSV58619506; called by muse, mutect2, varscan2
- DIXDC1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 117/261 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1027236169, COSV100180031, COSV59460966; called by muse, mutect2, varscan2
- DLC1 | c.2338G>A p.D780N (on ENST00000276297 / NM_001348081.2; = p.D343N on NM_006094.5) | Missense Mutation (SNP) | VAF 235/462 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV52300754; called by muse, varscan2
- DLC1 | c.479C>A p.S160Y | Missense Mutation (SNP) | VAF 21/468 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV52329143, COSV99364171; called by muse, mutect2
- DLGAP5 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 117/243 reads (48%) | catalogued as rs774608538, COSV55962038; called by muse, mutect2, varscan2
- DMD | c.6402G>T p.E2134D | Missense Mutation (SNP) | VAF 130/298 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63766419; called by mutect2, varscan2
- DMD | c.4046C>T p.S1349F | Missense Mutation (SNP) | VAF 117/385 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs763514033, COSV63742562; called by muse, mutect2, varscan2
- DMP1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 200/442 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as rs1009092274; called by muse, mutect2, varscan2
- DMRT1 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 152/331 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs764351242; called by muse, mutect2, varscan2
- DMTN | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 137/333 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371569595, COSV56111740; called by muse, mutect2, varscan2
- DMXL1 | c.6125G>A p.R2042H | Missense Mutation (SNP) | VAF 130/282 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1339119066, COSV60705408; called by muse, mutect2, varscan2
- DMXL2 | c.278G>T p.R93I | Missense Mutation (SNP) | VAF 100/191 reads (52%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV99195926; called by muse, mutect2, varscan2
- DNAH11 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 137/316 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995773912; called by muse, mutect2, varscan2
- DNAH12 | c.3673C>T p.R1225* (on ENST00000351747; = p.R1248* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 123/290 reads (42%) | catalogued as rs981533821; called by muse, mutect2, varscan2
- DNAH17 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 153/292 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs768308901, COSV101102013, COSV67758449; called by muse, mutect2, varscan2
- DNAH2 | c.2510G>A p.R837H | Missense Mutation (SNP) | VAF 193/391 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs779653586, COSV101209097; called by muse, mutect2, varscan2
- DNAH2 | c.8829G>T p.E2943D | Missense Mutation (SNP) | VAF 140/270 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV66716143; called by muse, mutect2, varscan2
- DNAH3 | c.8904G>T p.E2968D | Missense Mutation (SNP) | VAF 273/549 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104372710; called by muse, mutect2, varscan2
- DNAH6 | c.1523C>A p.S508Y | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99031389; called by muse, mutect2
- DNAH6 | c.8677C>T p.R2893* | Nonsense Mutation (SNP) | VAF 175/350 reads (50%) | catalogued as rs552500475, COSV52850352; called by muse, mutect2, varscan2
- DNAH7 | c.6223C>A p.L2075I | Missense Mutation (SNP) | VAF 167/364 reads (46%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.612); catalogued as rs1338784675, COSV56781678; called by muse, mutect2, varscan2
- DNAI4 | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 139/292 reads (48%) | catalogued as rs758550177, COSV64022904; called by muse, mutect2, varscan2
- DNAJA1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 140/303 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs141132012; called by muse, mutect2, varscan2
- DNAJA4 | c.851G>A p.R284Q (on ENST00000343789; = p.R313Q on NM_018602.3) | Missense Mutation (SNP) | VAF 129/274 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs751859584, COSV59425208; called by muse, mutect2, varscan2
- DNAJB1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 107/226 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs765857048; called by muse, mutect2, varscan2
- DNAJC13 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 183/360 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs547360849, COSV53446557; called by muse, mutect2, varscan2
- DNAJC13 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 147/319 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs202069439; called by muse, mutect2, varscan2
- DNAJC6 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 148/295 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs895749847, COSV54778444, COSV54778525; called by muse, mutect2, varscan2
- DNAJC7 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 115/246 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1346751595, COSV57267880; called by muse, mutect2, varscan2
- DNAL1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 130/300 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as COSV60727344; called by muse, mutect2, varscan2
- DNMBP | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs759738167, COSV60624289; called by muse, mutect2, varscan2
- DOC2A | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 184/418 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs747294200, COSV58752141; called by muse, mutect2, varscan2
- DOCK1 | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 161/355 reads (45%) | catalogued as COSV99733486; called by muse, mutect2, varscan2
- DOCK10 | c.4531C>A p.Q1511K | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as COSV51419606; called by muse, mutect2
- DOCK10 | c.3953C>A p.S1318Y | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51431635; called by muse, mutect2
- DOCK11 | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 239/500 reads (48%) | catalogued as COSV99354069; called by muse, mutect2, varscan2
- DOCK2 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 127/267 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56975150; called by muse, mutect2, varscan2
- DOCK6 | c.4738G>A p.D1580N | Missense Mutation (SNP) | VAF 152/334 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762402181; called by muse, mutect2, varscan2
- DOCK8 | c.6097C>T p.R2033C | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs751058288, COSV66619972; called by muse, mutect2, varscan2
- DPPA3 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV61502790; called by muse, mutect2, varscan2
- DPY19L1 | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99069720; called by muse, mutect2, varscan2
- DRC7 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 133/133 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs373094122; called by muse, mutect2, varscan2
- DSCAM | c.4771G>A p.E1591K | Missense Mutation (SNP) | VAF 202/455 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs556682802; called by muse, mutect2, varscan2
- DSCC1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 130/239 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs144655317; called by muse, mutect2, varscan2
- DSEL | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 274/525 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100025957, COSV59494476; called by muse, mutect2, varscan2
- DSEL | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 197/454 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs750994609, COSV59491191; called by muse, mutect2, varscan2
- DSG1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767678194, COSV57133741; called by muse, mutect2, varscan2
- DSG3 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 158/334 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as rs138945214; called by muse, mutect2, varscan2
- DSG3 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 133/308 reads (43%) | catalogued as rs1472943015, COSV57125252, COSV99934677; called by muse, mutect2, varscan2
- DST | c.20063C>A p.T6688N (on ENST00000361203 / NM_001374722.1; = p.T4385N on NM_015548.5) | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99759071; called by muse, mutect2, varscan2
- DST | c.11907C>A p.F3969L (on ENST00000361203 / NM_001374722.1; = p.F1557L on NM_015548.5) | Missense Mutation (SNP) | VAF 37/499 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.365); catalogued as COSV55027440; called by muse, mutect2
- DST | c.2489G>A p.R830Q (on ENST00000361203 / NM_001374722.1; = p.R504Q on NM_001723.6) | Missense Mutation (SNP) | VAF 156/325 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762435098; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 183/409 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1378629225; called by muse, mutect2, varscan2
- DUSP9 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 311/625 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as rs138533897; called by muse, mutect2, varscan2
- DUT | c.646C>T p.R216* (on ENST00000331200 / NM_001025248.2; = p.R128* on NM_001948.4) | Nonsense Mutation (SNP) | VAF 154/293 reads (53%) | catalogued as rs989363911; called by muse, mutect2, varscan2
- DVL2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 174/370 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as rs144205338, COSV50034537; called by muse, mutect2, varscan2
- DYNC1H1 | c.12076G>A p.D4026N | Missense Mutation (SNP) | VAF 147/296 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs768636289, COSV64140358; called by muse, mutect2, varscan2
- DYNC2H1 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs561232842, COSV62086954; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYNC2H1 | c.6044G>A p.R2015Q | Missense Mutation (SNP) | VAF 197/405 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs775984088, COSV62091815; called by muse, varscan2
- DYNC2H1 | c.7277G>A p.R2426H | Missense Mutation (SNP) | VAF 102/203 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs373521030, COSV62100802; called by muse, mutect2, varscan2
- DYNC2I1 | c.1815G>T p.E605D | Missense Mutation (SNP) | VAF 124/251 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751206395; called by muse, mutect2, varscan2
- DYRK1A | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs556482236, COSV100117324; called by muse, mutect2, varscan2
- DYSF | c.103A>G p.T35A | Missense Mutation (SNP) | VAF 170/417 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs985470984; called by muse, mutect2, varscan2
- DYTN | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 153/319 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs369410820; called by muse, mutect2, varscan2
- EBAG9 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200319904, COSV61753792; called by muse, mutect2, varscan2
- EBF2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68776583, COSV68780548; called by muse, varscan2
- ECE1 | c.1620C>A p.F540L | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV99941319; called by muse, mutect2
- ECE2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 191/399 reads (48%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs768830091; called by muse, mutect2, varscan2
- ECH1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 187/366 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.271); catalogued as rs1403167483; called by muse, mutect2, varscan2
- ECT2L | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 164/376 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs754540928, COSV62882962; called by muse, mutect2
- EEA1 | c.999G>T p.K333N | Missense Mutation (SNP) | VAF 102/238 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59287992; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 168/365 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs748024573, COSV66964361; called by muse, mutect2, varscan2
- EEF2K | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 128/295 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs775963419, COSV53787474; called by muse, mutect2, varscan2
- EEF2K | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 110/221 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs779040918; called by muse, mutect2, varscan2
- EFCAB13 | c.2792C>T p.S931L | Missense Mutation (SNP) | VAF 116/237 reads (49%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.024); catalogued as rs369709542, COSV58946115; called by muse, mutect2, varscan2
- EFCAB5 | c.904G>T p.G302* | Nonsense Mutation (SNP) | VAF 73/243 reads (30%) | catalogued as COSV57927047; called by mutect2, varscan2
- EFHC1 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 300/584 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs766799700; called by muse, mutect2, varscan2
- EFHC2 | c.436T>G p.F146V | Missense Mutation (SNP) | VAF 261/530 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV69555018; called by muse, mutect2, varscan2
- EFHC2 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 214/506 reads (42%) | catalogued as COSV69554155; called by muse, varscan2
- EFL1 | c.3025C>T p.R1009W | Missense Mutation (SNP) | VAF 125/281 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867514102; called by muse, mutect2, varscan2
- EFR3A | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 112/217 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1291653738, COSV54459529; called by muse, mutect2, varscan2
- EFR3B | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 186/365 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101241465; called by muse, varscan2
- EGF | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 126/241 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as rs147634717, COSV54486379; called by muse, mutect2, varscan2
- EGFLAM | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 133/268 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs745930197, COSV59310512; called by muse, mutect2, varscan2
- EGFR | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 279/578 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768336804, COSV51806564; called by muse, mutect2, varscan2
- EGLN1 | c.1024A>G p.I342V | Missense Mutation (SNP) | VAF 115/435 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs1411721495; called by muse, mutect2, varscan2
- EGR2 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 242/511 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54347773; called by muse, mutect2, varscan2
- EHBP1 | c.3593C>T p.A1198V | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99859721; called by muse, mutect2, varscan2
- EHF | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 126/257 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757126229, COSV57669499; called by muse, mutect2, varscan2
- EIF4E2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 301/614 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs925320031; called by muse, mutect2, varscan2
- ELOA | c.1807C>A p.L603I | Missense Mutation (SNP) | VAF 119/245 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99072567; called by muse, mutect2, varscan2
- ELOVL1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 195/374 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201270403; called by muse, mutect2, varscan2
- ELP2 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 164/358 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371310428, CM118299; called by muse, mutect2, varscan2
- EMC2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs1030080319; called by muse, mutect2, varscan2
- EML3 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 291/623 reads (47%) | catalogued as COSV53882422; called by muse, mutect2, varscan2
- ENDOD1 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 144/280 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773730577; called by muse, mutect2, varscan2
- ENO1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 179/365 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs371689591; called by muse, mutect2, varscan2
- ENO2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 165/365 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs782101405; called by muse, mutect2, varscan2
- ENOX2 | c.1108C>T p.R370C (on ENST00000338144 / NM_001382520.1; = p.R341C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/235 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199818795, COSV57650385; called by muse, mutect2, varscan2
- ENPEP | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 215/455 reads (47%) | catalogued as rs143343563, COSV54448047; called by muse, varscan2
- ENPEP | c.2672G>A p.R891Q | Missense Mutation (SNP) | VAF 147/295 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770598233, COSV54448376; called by muse, mutect2, varscan2
- EOLA2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 350/756 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as rs144047890; called by muse, mutect2
- EOMES | c.1625C>A p.S542Y | Missense Mutation (SNP) | VAF 177/414 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1249582464, COSV99841940; called by muse, mutect2, varscan2
- EP400 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 104/245 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.654); catalogued as rs766432250, COSV57780225; called by muse, mutect2, varscan2
- EPB41L5 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 113/274 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1414991675, COSV55354222; called by muse, mutect2, varscan2
- EPC1 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 123/293 reads (42%) | catalogued as COSV53924607; called by muse, mutect2, varscan2
- EPHA5 | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 185/429 reads (43%) | catalogued as COSV99899142; called by muse, mutect2, varscan2
- EPHA5 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 160/346 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs151302542; called by muse, mutect2, varscan2
- EPHB1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 141/291 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs764139128, COSV67657222, COSV67674992; called by muse, mutect2, varscan2
- EPHX2 | c.1347C>A p.F449L | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV66843959; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 183/362 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0.05); catalogued as COSV51615868; called by muse, mutect2, varscan2
- EPS15 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs762929521; called by muse, mutect2, varscan2
- EPS15 | c.1816A>C p.S606R | Missense Mutation (SNP) | VAF 136/297 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV65540465; called by muse, mutect2, varscan2
- EPS8 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 176/361 reads (49%) | catalogued as rs1457535054, COSV55528972; called by muse, mutect2, varscan2
- ERICH5 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 202/391 reads (52%) | catalogued as COSV59315405; called by muse, mutect2, varscan2
- ERMN | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 195/387 reads (50%) | catalogued as rs1469712056, COSV101263012, COSV68075619; called by muse, mutect2, varscan2
- ERO1A | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 122/269 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs774350848; called by muse, mutect2, varscan2
- ERP44 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52431460; called by muse, mutect2
- ESF1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 152/291 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs186231642, COSV52518687, COSV52523168; called by muse, mutect2, varscan2
- ESYT3 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 170/338 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.342); catalogued as rs769328420, COSV56679687; called by muse, mutect2, varscan2
- ETV3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 192/669 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs1163203810, COSV58748797; called by muse, mutect2, varscan2
- EVC2 | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 124/263 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV60397979; called by muse, mutect2, varscan2
- EVL | c.992C>T p.S331L (on ENST00000402714 / NM_001330221.2; = p.S333L on NM_016337.3) | Missense Mutation (SNP) | VAF 166/354 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV67375968; called by muse, mutect2, varscan2
- EVPL | c.4715G>T p.R1572I | Missense Mutation (SNP) | VAF 212/453 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1213641169; called by mutect2, varscan2
- EXOC2 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 103/241 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV57863551; called by muse, mutect2, varscan2
- EXOC4 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 13/347 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs1032578634, COSV54091184; called by muse, mutect2
- EXOC6 | c.1431G>T p.K477N | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV53322737; called by muse, mutect2, varscan2
- EXOC8 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 191/612 reads (31%) | catalogued as COSV50478059; called by muse, mutect2, varscan2
- EXPH5 | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 37/419 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs146870938; called by muse, mutect2
- EXTL2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 158/328 reads (48%) | catalogued as COSV64472964; called by muse, varscan2
- EYS | c.6957C>A p.F2319L | Missense Mutation (SNP) | VAF 153/345 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV65471997; called by muse, mutect2, varscan2
- F5 | c.3409C>A p.Q1137K | Missense Mutation (SNP) | VAF 148/445 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as CM105383; called by muse, mutect2, varscan2
- F8 | c.3407C>T p.S1136F | Missense Mutation (SNP) | VAF 208/462 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.483); catalogued as COSV64273005, COSV64273639; called by muse, mutect2, varscan2
- F9 | c.89-1G>T p.X30_splice | Splice Site (SNP) | VAF 144/265 reads (54%) | catalogued as CS930794, CS941473, CS961561, CX962377; called by muse, mutect2, varscan2
- FAAH2 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs201590323; called by muse, mutect2, varscan2
- FAAH2 | c.1166G>T p.S389I | Missense Mutation (SNP) | VAF 182/443 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.492); catalogued as rs752160314; called by mutect2, varscan2
- FAF2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 153/349 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV56133038; called by muse, mutect2, varscan2
- FAM107B | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 300/607 reads (49%) | catalogued as rs778239622, COSV99473424, COSV99474364; called by muse, mutect2, varscan2
- FAM135A | c.1760C>A p.S587Y | Missense Mutation (SNP) | VAF 194/394 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99525747; called by muse, mutect2, varscan2
- FAM167A | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 164/346 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758382682, COSV52668399; called by muse, mutect2, varscan2
- FAM171B | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 152/337 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100488358; called by muse, mutect2, varscan2
- FAM186A | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 154/386 reads (40%) | catalogued as rs541010309, COSV59256231; called by muse, mutect2, varscan2
- FAM189A2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 136/259 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs764688447; called by muse, mutect2, varscan2
- FAM210B | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 220/448 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs17851557; called by muse, mutect2, varscan2
- FAM237A | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 165/317 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV101405598, COSV69304999; called by muse, mutect2, varscan2
- FAM47A | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 338/694 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV100650044; called by muse, varscan2
- FAM47C | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 217/446 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.635); catalogued as rs1328446187; called by muse, mutect2, varscan2
- FAM71A | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 56/794 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs773097173, COSV54236120; called by muse, mutect2
- FAM83B | c.2774G>A p.R925Q | Missense Mutation (SNP) | VAF 154/367 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs181400966; called by muse, mutect2, varscan2
- FAM83G | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 189/413 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs376887547; called by muse, mutect2, varscan2
- FANCB | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 197/385 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs1057515811, COSV60759570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANK1 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 150/326 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as COSV64137720; called by muse, mutect2, varscan2
- FAR2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 106/233 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as rs1475516172; called by muse, mutect2, varscan2
- FAT1 | c.2979G>T p.K993N | Missense Mutation (SNP) | VAF 203/466 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs1397804525, COSV104437747, COSV71673670; called by muse, mutect2, varscan2
- FAT3 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 185/398 reads (46%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.806); catalogued as rs780987790, COSV53079281; called by muse, mutect2, varscan2
- FAT3 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 177/377 reads (47%) | catalogued as COSV53072200, COSV53124569, COSV99963822; called by muse, mutect2, varscan2
- FBN1 | c.1035C>A p.C345* | Nonsense Mutation (SNP) | VAF 161/325 reads (50%) | catalogued as CM098623; called by muse, varscan2
- FBN3 | c.5428C>T p.R1810W | Missense Mutation (SNP) | VAF 154/320 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as rs902177398; called by muse, mutect2, varscan2
- FBXL3 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 146/306 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs560551710, COSV62918460; called by muse, mutect2, varscan2
- FBXO38 | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 167/389 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV57030777; called by muse, mutect2, varscan2
- FBXO38 | c.3208C>T p.R1070* (on ENST00000340253 / NM_205836.3; = p.R995* on NM_030793.5) | Nonsense Mutation (SNP) | VAF 109/276 reads (39%) | catalogued as rs904657927, COSV57030854; called by muse, mutect2, varscan2
- FBXO4 | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 140/294 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV55852313; called by muse, varscan2
- FBXW10 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 124/269 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1298042791; called by muse, mutect2, varscan2
- FBXW2 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 123/308 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs761775371; called by muse, mutect2, varscan2
- FCHSD2 | c.333C>A p.F111L | Missense Mutation (SNP) | VAF 138/308 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60812008; called by muse, mutect2, varscan2
- FCN2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 139/343 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs369954653; called by muse, mutect2, varscan2
- FDPS | c.353A>C p.N118T | Missense Mutation (SNP) | VAF 143/413 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs907532468; called by muse, mutect2, varscan2
- FEM1B | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 168/361 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.13); catalogued as rs142905378, COSV60987969; called by muse, mutect2, varscan2
- FER1L6 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 264/269 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs191271444; called by muse, mutect2, varscan2
- FES | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 185/382 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374728358; called by muse, mutect2, varscan2
- FES | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 136/300 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.631); catalogued as rs749673968, COSV60996495; called by muse, mutect2, varscan2
- FGA | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 126/286 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs763555716, COSV57393105; called by muse, mutect2, varscan2
- FGF19 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 217/428 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as COSV53736124; called by muse, mutect2, varscan2
- FGFR4 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 132/303 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269001777, COSV52801661; called by muse, mutect2, varscan2
- FGL2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 188/380 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as rs1459657752, COSV50381411; called by muse, mutect2, varscan2
- FH | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 118/309 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs200412958, COSV100845004, COSV100845021; called by muse, mutect2, varscan2
- FHOD3 | c.3703C>T p.R1235W (on ENST00000359247 / NM_001281739.3; = p.R1252W on NM_025135.5) | Missense Mutation (SNP) | VAF 98/288 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs1218875049, COSV57180298; called by muse, mutect2, varscan2
- FIGNL1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 53/439 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63553302; called by muse, mutect2, varscan2
- FILIP1 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 147/308 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.343); catalogued as rs868698674, COSV52728473; called by muse, mutect2, varscan2
- FILIP1 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 162/495 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs147080592; called by muse, mutect2, varscan2
- FKBP3 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53534311; called by muse, mutect2, varscan2
- FLII | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 155/351 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs201233040, COSV57497649; called by muse, mutect2, varscan2
- FLNA | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 272/517 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.599); catalogued as rs782373438; called by muse, mutect2, varscan2
- FLRT3 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 147/317 reads (46%) | catalogued as COSV54002106; called by muse, mutect2, varscan2
- FLT4 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 252/488 reads (52%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs752512978, COSV56105948; called by muse, mutect2, varscan2
- FMN2 | c.4402C>T p.R1468C | Missense Mutation (SNP) | VAF 104/359 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs748812254, COSV100144530, COSV60425638; called by muse, mutect2, varscan2
- FMNL3 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 155/343 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs776117483, COSV53305012; called by muse, mutect2, varscan2
- FMO4 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 165/553 reads (30%) | catalogued as COSV100882041, COSV63000984; called by muse, mutect2, varscan2
- FN1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 117/256 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs1272001331, COSV60546022; called by muse, mutect2, varscan2
- FNDC3A | c.274C>T p.R92* (on ENST00000492622 / NM_001079673.2; = p.R36* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 18/376 reads (5%) | catalogued as rs1284518617, COSV65695143; called by muse, mutect2
- FNDC3B | c.2378C>A p.S793Y | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV61037832; called by muse, mutect2, varscan2
- FNDC7 | c.1997G>A p.G666D | Missense Mutation (SNP) | VAF 243/493 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763013847; called by muse, mutect2, varscan2
- FOXD4L1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 211/518 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.374); catalogued as rs755139743, COSV52075704; called by muse, mutect2
- FOXD4L3 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 78/596 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1446583050; called by muse, mutect2
- FOXD4L5 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 21/647 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1184288517, COSV66240433; called by muse, mutect2
- FOXJ3 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 257/501 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as rs377432876; called by muse, mutect2, varscan2
- FRAS1 | c.4903C>T p.R1635W | Missense Mutation (SNP) | VAF 144/339 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs764372113; called by muse, mutect2, varscan2
- FREM2 | c.3092C>A p.S1031Y | Missense Mutation (SNP) | VAF 194/427 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.205); catalogued as COSV54830140; called by mutect2, varscan2
- FRMD3 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 28/512 reads (5%) | catalogued as COSV100170918; called by muse, mutect2
- FRMD6 | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 112/283 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV100655674; called by muse, mutect2, varscan2
- FRMD7 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 257/550 reads (47%) | catalogued as COSV100048847, COSV100048949; called by muse, mutect2, varscan2
- FRMD7 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 250/510 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV53745261; called by muse, mutect2, varscan2
- FRYL | c.4396C>T p.R1466C | Missense Mutation (SNP) | VAF 160/328 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770021669; called by muse, mutect2, varscan2
- FRYL | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 125/268 reads (47%) | catalogued as COSV51962506; called by muse, mutect2, varscan2
- FSD1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs1189253379, COSV99696962; called by muse, mutect2
- FSIP2 | c.15121C>A p.Q5041K | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV58077376; called by muse, mutect2, varscan2
- FSIP2 | c.16948C>T p.R5650* | Nonsense Mutation (SNP) | VAF 134/274 reads (49%) | catalogued as rs746547008, COSV100555848, COSV58087277; called by muse, mutect2, varscan2
- FSIP2 | c.19333G>T p.D6445Y | Missense Mutation (SNP) | VAF 13/307 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1379596473, COSV58085126; called by muse, mutect2
- FUCA2 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 122/222 reads (55%) | catalogued as COSV99136078; called by muse, mutect2, varscan2
- GAB1 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53759426, COSV99527975; called by muse, mutect2, varscan2
- GABRA4 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 208/414 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV51924220; called by muse, mutect2, varscan2
- GABRG2 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 121/273 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.396); catalogued as rs1445637165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAD1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 109/256 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs1271415571, COSV60152097; called by muse, mutect2, varscan2
- GAD1 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 156/355 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.739); catalogued as rs771882638, COSV64025155, COSV64025272; called by muse, mutect2, varscan2
- GALNT12 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 220/466 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs776800914; called by muse, mutect2, varscan2
- GALNT14 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 142/327 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs148126284; called by muse, mutect2, varscan2
- GALNT15 | c.1828G>T p.E610* | Nonsense Mutation (SNP) | VAF 177/428 reads (41%) | catalogued as rs1291771271; called by muse, mutect2
- GALNT2 | c.1185C>A p.F395L | Missense Mutation (SNP) | VAF 156/544 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs754934176, COSV64194651, COSV64197639; called by muse, varscan2
- GALNT5 | c.951C>A p.F317L | Missense Mutation (SNP) | VAF 127/272 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1223716694; called by muse, mutect2, varscan2
- GALNT8 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 131/338 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52901465; called by muse, mutect2, varscan2
- GARNL3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 106/245 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs775082951, COSV59227089; called by muse, mutect2, varscan2
- GAS2L2 | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 262/491 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs782603064; called by muse, mutect2, varscan2
- GBA | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 189/619 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs758447515, CM980823, COSV59169412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBP1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 178/326 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs750208719, COSV65084564; called by muse, mutect2, varscan2
- GBP3 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 88/242 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.286); catalogued as rs780622494, COSV52518396; called by muse, mutect2, varscan2
- GBP6 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 189/391 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs756837037; called by muse, mutect2, varscan2
- GCNA | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 378/891 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.644); catalogued as rs767922902, COSV65466479; called by muse, mutect2, varscan2
- GCNT3 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 248/504 reads (49%) | catalogued as COSV68531940; called by muse, mutect2
- GDF10 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 330/695 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1429920615; called by muse, mutect2, varscan2
- GEN1 | c.1793C>A p.S598Y | Missense Mutation (SNP) | VAF 172/382 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs1360537691; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 16/340 reads (5%) | catalogued as COSV61324419; called by muse, mutect2
- GFPT1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 139/288 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV61947287; called by muse, mutect2, varscan2
- GFPT2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 198/399 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs753499695, COSV53808391; called by muse, mutect2, varscan2
- GHR | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 138/284 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373412197; called by muse, mutect2, varscan2
- GIGYF2 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 103/207 reads (50%) | catalogued as COSV65246402; called by muse, mutect2, varscan2
- GJA3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 245/495 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs781023239, COSV53834771; called by muse, mutect2, varscan2
- GK | c.1513C>T p.R505C (on ENST00000427190 / NM_001205019.2; = p.R499C on NM_000167.6) | Missense Mutation (SNP) | VAF 130/290 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs770290868, COSV66732271; called by muse, mutect2, varscan2
- GLB1L | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 127/275 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs757310085, COSV55476479; called by muse, mutect2, varscan2
- GLB1L3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 197/367 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV101111108; called by muse, mutect2, varscan2
- GLDC | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV58685224; called by muse, mutect2, varscan2
- GLG1 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 148/148 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV99215891; called by muse, mutect2, varscan2
- GLI3 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 287/551 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs1489678675; called by muse, mutect2, varscan2
- GLOD4 | c.434G>A p.R145H (on ENST00000301328 / NM_001366247.1; = p.R130H on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/231 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56755300; called by muse, mutect2, varscan2
- GNAI1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 195/370 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1562844525; called by muse, mutect2, varscan2
- GNAT2 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 133/279 reads (48%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.574); catalogued as COSV63555434; called by muse, mutect2, varscan2
- GNB4 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 150/297 reads (51%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.856); catalogued as rs955229785, COSV99224037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNG4 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 102/355 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs764998095, COSV63999285; called by muse, mutect2, varscan2
- GNLY | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 167/372 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs149497301; called by muse, varscan2
- GNPAT | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs774134716, COSV64153478; called by muse, mutect2, varscan2
- GOLGA6L7 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 119/259 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.23); catalogued as rs747558475, COSV101629691; called by muse, mutect2, varscan2
- GOLGA8M | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 193/442 reads (44%) | catalogued as rs539256593; called by muse, mutect2, varscan2
- GORAB | c.663G>A p.R221= | Splice Region (SNP) | VAF 55/254 reads (22%) | catalogued as rs747506136; called by muse, mutect2, varscan2
- GORAB | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 121/424 reads (29%) | catalogued as rs1273628015; called by muse, mutect2, varscan2
- GP2 | c.554C>A p.T185N (on ENST00000381362 / NM_001007240.3; = p.T182N on NM_001502.4) | Missense Mutation (SNP) | VAF 145/335 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as rs751840927; called by muse, mutect2, varscan2
- GPATCH8 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 185/353 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV59194383; called by muse, mutect2, varscan2
- GPC2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 207/442 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1229970899, COSV52785576; called by muse, mutect2, varscan2
- GPC5 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV65580545; called by muse, mutect2, varscan2
- GPLD1 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 147/311 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.071); catalogued as rs778060726, COSV57753825; called by muse, mutect2, varscan2
- GPM6B | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 206/395 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0.058); catalogued as rs1253105068; called by muse, mutect2, varscan2
- GPR101 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 251/583 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs137929096; called by muse, mutect2, varscan2
- GPR137 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 22/499 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.138); catalogued as rs1234857518, COSV57402907; called by muse, mutect2
- GPR149 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 224/416 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67665860; called by muse, mutect2, varscan2
- GPR176 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 264/538 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs761710592, COSV104406876; called by muse, mutect2, varscan2
- GPR82 | c.880C>A p.L294I | Missense Mutation (SNP) | VAF 153/341 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV56888141; called by muse, mutect2, varscan2
- GREB1 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774958802; called by muse, mutect2, varscan2
- GREB1L | c.5695C>T p.R1899C | Missense Mutation (SNP) | VAF 178/365 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346184582; called by muse, mutect2, varscan2
- GRIA2 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 115/245 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52385092; called by muse, mutect2, varscan2
- GRIA2 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 110/290 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs1463020369, COSV52393314; called by muse, mutect2, varscan2
- GRIA2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 136/286 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs777296512, COSV52391073; called by muse, mutect2, varscan2
- GRIK2 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 180/362 reads (50%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.964); catalogued as COSV59720904; called by muse, varscan2
- GRIK4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 138/306 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as rs780640351, COSV70801363; called by muse, mutect2, varscan2
- GRIN2C | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 151/322 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425898910, COSV99500978; called by muse, mutect2, varscan2
- GRK3 | c.494T>G p.F165C | Missense Mutation (SNP) | VAF 117/275 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs762659935, COSV60799011; called by muse, mutect2, varscan2
- GRK3 | c.970C>A p.L324I | Missense Mutation (SNP) | VAF 97/195 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100151737; called by muse, mutect2, varscan2
- GRM1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 245/478 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1196671438, COSV51159383, COSV51197406; called by muse, mutect2, varscan2
- GRM5 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 210/454 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59596448; called by muse, mutect2, varscan2
- GRM8 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 53/580 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs540378963; called by muse, mutect2
- GSDMA | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 116/248 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs547737973, COSV56980023; called by muse, mutect2, varscan2
- GSDMC | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 126/253 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs770331372, COSV52694670; called by muse, mutect2
- GSR | c.764C>A p.S255Y | Missense Mutation (SNP) | VAF 145/314 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1301297124; called by muse, mutect2, varscan2
- GUCY2C | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 144/390 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs1057520052, COSV53789090; ClinVar: uncertain significance; called by muse, mutect2
- GYS1 | c.1002C>A p.F334L | Missense Mutation (SNP) | VAF 117/233 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV54402885; called by muse, mutect2, varscan2
- H1-1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 194/379 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1313858586; called by muse, mutect2, varscan2
- H2AZ2 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 143/335 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV56062414; called by muse, mutect2, varscan2
- H2BC14 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 139/267 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1474071318, COSV60797493, COSV60797855; called by muse, mutect2, varscan2
- H3-4 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 193/512 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV64210769; called by muse, mutect2, varscan2
- H3-5 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 240/501 reads (48%) | catalogued as COSV61187197; called by muse, mutect2, varscan2
- H4C9 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 184/423 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100574952; called by muse, varscan2
- HADH | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 169/338 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs375910422; called by muse, mutect2, varscan2
- HAO1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 141/318 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs148598378; called by muse, mutect2, varscan2
- HAPLN1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 229/465 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs115901495, COSV57147386; called by muse, mutect2, varscan2
- HARS1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 135/360 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752549829, COSV56906738; called by muse, mutect2, varscan2
- HAUS5 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 132/256 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs370335275; called by muse, mutect2, varscan2
- HAUS6 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 143/337 reads (42%) | catalogued as rs765822489; called by muse, mutect2
- HCFC1 | c.5635G>A p.E1879K | Missense Mutation (SNP) | VAF 87/622 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs868959030, COSV60074325; called by muse, mutect2, varscan2
4,115 further variants in this file (2,908 protein-altering or splice-affecting, 1,006 silent, 201 other) are not listed here.
